Somatic mutation profile of tumor specimen C3L-00599-01 (aliquot CPT0081260007_1) from CPTAC case C3L-00599, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 62.4 years (22,781 days).
Specimen C3L-00599-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4682f211-1dba-498b-9c2b-01ebaec97078.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00599-31 (Blood Derived Normal), aliquot CPT0081300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/631a495c-d946-422b-a688-845cbb0d9c7f

The open-access MAF lists 55 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 10, Intron 4, Nonsense Mutation 3, 5'UTR 2, RNA 2, Splice Region 1, Frame Shift Del 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 47/616 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2
- ACTN2 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 42/677 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1246542277, COSV63978630; ClinVar: uncertain significance; called by muse, mutect2
- ALAS2 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as CM114507; called by muse, mutect2, varscan2
- ARID1A | c.791C>A p.S264* | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | catalogued as COSV61381323; called by muse, mutect2
- FOSL2 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 25/299 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334038053, COSV53103773; called by muse, mutect2
- FRMD3 | c.606C>G p.S202R | Missense Mutation (SNP) | VAF 18/372 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV58459936; called by muse, mutect2
- HK3 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 44/496 reads (9%) | SIFT tolerated (0.97); PolyPhen benign (0.023); catalogued as rs150272942; called by muse, mutect2
- MYT1 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 22/590 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1224565423, COSV60505485; called by muse, mutect2
- NUP210L | c.3029C>T p.S1010F | Missense Mutation (SNP) | VAF 31/449 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.545); catalogued as COSV55157757; called by muse, mutect2
- RNF222 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1329313606; called by muse, mutect2, varscan2
- SEMA5B | c.2426C>T p.P809L | Missense Mutation (SNP) | VAF 40/521 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV52094717; called by muse, mutect2
- TBC1D9 | c.3550G>A p.G1184R | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.455); catalogued as rs778747040; called by muse, mutect2
- TMEM100 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 48/511 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs746630975, COSV70118095, COSV70118125; called by muse, mutect2
- TOX2 | c.1070G>A p.R357Q (on ENST00000358131 / NM_001098798.2; = p.R333Q on NM_032883.3) | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.978); catalogued as rs773686339, COSV57882392; called by muse, mutect2
- ZNF415 | c.1580G>T p.S527I | Missense Mutation (SNP) | VAF 72/423 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV54702581; called by muse, mutect2, varscan2
- ABCC6 | c.2509T>C p.Y837H | Missense Mutation (SNP) | VAF 21/554 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- AGAP3 | c.586G>A p.V196M (on ENST00000622464; = p.V232M on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- APOA5 | c.50-1G>A p.X17_splice | Splice Site (SNP) | VAF 31/1035 reads (3%) | called by muse, mutect2
- APPBP2 | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- BCL2L14 | c.812A>C p.K271T | Missense Mutation (SNP) | VAF 89/827 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- COMMD9 | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 43/519 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); called by muse, mutect2
- CROCC2 | c.2973G>T p.E991D | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- FAM184B | c.158A>T p.N53I | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FOXK1 | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 28/676 reads (4%) | called by muse, mutect2
- GLI3 | c.124+5G>C | Splice Region (SNP) | VAF 82/736 reads (11%) | called by muse, mutect2, varscan2
- HOOK2 | c.1463A>G p.H488R | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.119); called by muse, mutect2
- KCNA5 | c.901A>G p.S301G | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.248); called by muse, mutect2
- PCDH17 | c.1900C>A p.H634N | Missense Mutation (SNP) | VAF 121/607 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- PLAA | c.2315_2318del p.I772Kfs*12 | Frame Shift Del (DEL) | VAF 29/206 reads (14%) | called by mutect2, pindel, varscan2
- RYR2 | c.11053G>A p.D3685N | Missense Mutation (SNP) | VAF 39/508 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC12A2 | c.1064T>C p.L355S | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ST6GAL2 | c.544A>G p.R182G | Missense Mutation (SNP) | VAF 62/469 reads (13%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STX8 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 30/349 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TEAD3 | c.104G>A p.W35* | Nonsense Mutation (SNP) | VAF 27/552 reads (5%) | called by muse, mutect2
- TFIP11 | c.1198T>C p.C400R | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZBED9 | c.2363G>T p.S788I | Missense Mutation (SNP) | VAF 55/419 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ASB17 | c.810C>T p.T270= | Silent (SNP) | VAF 26/328 reads (8%) | catalogued as COSV52409194; called by muse, mutect2
- CCDC166 | c.237C>T p.Y79= | Silent (SNP) | VAF 20/570 reads (4%) | catalogued as rs1554616961, COSV101545814; called by muse, mutect2
- DAND5 | c.138G>T p.G46= | Silent (SNP) | VAF 13/133 reads (10%) | called by muse, mutect2
- EMX1 | c.351C>T p.L117= | Silent (SNP) | VAF 16/265 reads (6%) | called by muse, mutect2
- EMX2 | c.681G>T p.G227= | Silent (SNP) | VAF 92/882 reads (10%) | catalogued as COSV101463626; called by muse, mutect2, varscan2
- ERBB2 | c.930C>T p.S310= | Silent (SNP) | VAF 47/622 reads (8%) | catalogued as rs974531857, COSV54068756; called by muse, mutect2
- FBXO10 | c.2526C>T p.N842= | Silent (SNP) | VAF 18/158 reads (11%) | called by mutect2, varscan2
- LSAMP | c.222A>G p.G74= | Silent (SNP) | VAF 22/794 reads (3%) | called by muse, mutect2
- SPIN2A | c.621T>C p.D207= | Silent (SNP) | VAF 67/399 reads (17%) | called by muse, mutect2, varscan2
- TACR3 | c.780G>A p.L260= | Silent (SNP) | VAF 49/556 reads (9%) | catalogued as rs768209062; ClinVar: likely benign; called by muse, mutect2
- DPYS | c.1444-17G>A | Intron (SNP) | VAF 30/672 reads (4%) | catalogued as rs774996693; called by muse, mutect2
- GSDMD | c.580-22C>T | Intron (SNP) | VAF 57/517 reads (11%) | catalogued as rs780783370, COSV52796670; called by muse, mutect2, varscan2
- MIR1185-1 | n.69T>C | RNA (SNP) | VAF 38/203 reads (19%) | called by muse, mutect2, varscan2
- NLGN4Y | c.-332C>G | 5'UTR (SNP) | VAF 95/460 reads (21%) | called by muse, mutect2, varscan2
- RN7SL214P | chr15:77918964 T>C | 5'Flank (SNP) | VAF 54/1359 reads (4%) | called by muse, mutect2
- SLC6A10P | n.3666C>T | RNA (SNP) | VAF 20/174 reads (11%) | catalogued as rs1481919023; called by mutect2, varscan2
- TMEM258 | c.3+23C>T | Intron (SNP) | VAF 48/610 reads (8%) | called by muse, mutect2
- TNC | c.4579+4151G>T | Intron (SNP) | VAF 32/228 reads (14%) | called by muse, varscan2
- ZNF716 | c.-9C>T | 5'UTR (SNP) | VAF 26/528 reads (5%) | catalogued as rs782340963, COSV70780074; called by muse, mutect2
